Somatic mutation profile of tumor specimen TCGA-E8-A438-01A (aliquot TCGA-E8-A438-01A-11D-A23U-08) from TCGA case TCGA-E8-A438, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 24.0 years (8,752 days).
Specimen TCGA-E8-A438-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfb916f1-41cb-40bd-9505-0cfa309171e9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E8-A438-10B (Blood Derived Normal), aliquot TCGA-E8-A438-10B-01D-A23U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/58f3317d-cc31-4b4a-bd51-b5ea8eb827f5

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 5, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO8 | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 73/211 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1212896037, COSV50175176; called by muse, mutect2, varscan2
- BBS7 | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as COSV99144784; called by muse, mutect2, varscan2
- HELQ | c.2716A>T p.I906F | Missense Mutation (SNP) | VAF 16/209 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV99787341; called by muse, mutect2
- SLCO2B1 | c.1390G>A p.G464S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771234191, COSV99214155; called by muse, mutect2, varscan2
- SYNPO2 | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV100204655, COSV100206465; called by muse, mutect2, varscan2
- FCRL3 | c.1017G>A p.L339= | Silent (SNP) | VAF 27/98 reads (28%) | catalogued as COSV100942722; called by muse, mutect2, varscan2
- MYF5 | c.6C>T p.D2= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV57356299; called by muse, mutect2, varscan2
- PIK3R5 | c.1134C>T p.S378= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV99352736; called by muse, mutect2, varscan2
